CPTAC case C3N-01199 — Brain — Gliomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Gliomas; Primary site: Brain. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/b1b27c1a-4c4b-4909-9942-98e2ef316ef3

Demographics
Sex at birth: male; Race: white; Year of birth: 1968; Vital status: Dead; Days to death: 366 days (1.0 years); Year of death: 2018; Country of birth: Poland.

Diagnoses (1)
1. Oligodendroglioma, NOS: ICD-O-3 morphology code: 9450/3; Tissue or organ of origin: Brain, NOS; Site of resection or biopsy: Frontal lobe; Age at diagnosis: 48.9 years (17,847 days); Year of diagnosis: 2017; Tumor grade: G2.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-01199-04: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Frontal Lobe; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -59 days; Initial weight: 362 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-01199-24: Section location: Frontal Lobe; Percent tumor nuclei: 65; Percent necrosis: 1.
- Sample C3N-01199-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -59 days; Method of sample procurement: Blood Draw.
